Somatic mutation profile of tumor specimen TARGET-10-PARCBE-09A (aliquot TARGET-10-PARCBE-09A-01D) from TARGET case TARGET-10-PARCBE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,823 days).
Specimen TARGET-10-PARCBE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac8ae96d-57d6-4c85-9653-d9ae69b0d6f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCBE-10A (Blood Derived Normal), aliquot TARGET-10-PARCBE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23446826-a8f6-478a-bdd0-4fc76be3accd

The open-access MAF lists 30 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, 3'UTR 2, Frame Shift Del 2, Intron 2, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18B | c.239G>A p.R80H | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.809); catalogued as rs774619870; called by muse, mutect2, varscan2
- BRWD3 | c.3592C>T p.R1198C | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386861640; called by muse, mutect2, varscan2
- COL13A1 | c.1114G>A p.E372K (on ENST00000398978 / NM_001130103.2; = p.E315K on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1236197890; called by muse, mutect2, varscan2
- CSGALNACT1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.329); catalogued as COSV100174968; called by muse, mutect2
- KRTCAP3 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1213041908, COSV99275238; called by muse, mutect2
- SH3RF2 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs150009220, COSV63041803; called by muse, mutect2, varscan2
- TRIM49C | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.029); catalogued as rs1345786121; called by muse, mutect2, varscan2
- ZNF782 | c.1777G>C p.E593Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100001630, COSV56654489; called by muse, mutect2, varscan2
- ZNF782 | c.1493G>A p.R498K | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV56651717; called by muse, mutect2, varscan2
- ZNF782 | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs770441383, COSV56651830; called by muse, mutect2, varscan2
- CSMD1 | c.6446_6447insGGGC p.Y2149* (on ENST00000520002; = p.Y2148* on NM_033225.6) | Nonsense Mutation (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- DNASE1L1 | c.755del p.F252Sfs*21 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- LEF1 | c.928A>G p.M310V | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- PANX3 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2
- SFXN1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SIAE | c.320A>G p.N107S | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TBL1XR1 | c.420_423delinsCC p.I141Rfs*3 | Frame Shift Del (DEL) | VAF 11/25 reads (44%) | called by pindel, varscan2*
- TRAJ10 | chr14:22533495 TGATACTC>CCCCGGG | Missense Mutation (DEL) | VAF 54/130 reads (42%) | called by pindel, varscan2*
- DPRX | c.516C>T p.C172= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs755247548, COSV64949428; called by muse, mutect2, varscan2
- FAM222A | c.831G>T p.G277= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs767676227; called by muse, mutect2, varscan2
- FLT4 | c.102C>T p.I34= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1400540057; called by muse, mutect2, varscan2
- GUSB | c.1557G>T p.L519= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- L3MBTL4 | c.570A>G p.K190= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs773409850; called by muse, mutect2, varscan2
- MYO15A | c.5506C>T p.L1836= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99234714; called by muse, mutect2
- SYNE1 | c.6153T>C p.A2051= (on ENST00000367255 / NM_182961.4; = p.A2058= on NM_033071.3) | Silent (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-11386G>A | Intron (SNP) | VAF 4/88 reads (5%) | catalogued as rs1054693327; called by muse, mutect2
- AJAP1 | c.*5281C>T | 3'UTR (SNP) | VAF 7/98 reads (7%) | catalogued as rs1038441691; called by muse, mutect2
- AP000769.3 | chr11:65503543 A>G | 5'Flank (SNP) | VAF 14/76 reads (18%) | called by muse, mutect2, varscan2
- CDK5RAP3 | c.184+34C>G | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- NCOA6 | c.*87C>A | 3'UTR (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
